Somatic mutation profile of tumor specimen TCGA-WE-A8ZX-06A (aliquot TCGA-WE-A8ZX-06A-11D-A372-08) from TCGA case TCGA-WE-A8ZX, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 45.9 years (16,762 days).
Specimen TCGA-WE-A8ZX-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0e70d69-7710-41df-8018-5707d4067e84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-A8ZX-10A (Blood Derived Normal), aliquot TCGA-WE-A8ZX-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/366baee5-9227-4d12-8ab4-f570430b0ab0

The open-access MAF lists 693 somatic variants for this specimen: 443 protein-altering or splice-affecting, 242 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 404, Silent 242, Nonsense Mutation 24, Splice Site 7, Splice Region 5, RNA 5, Intron 3, Translation Start Site 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FUS | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs121909668, CM091086, CM091090, CM104702, COSV54215258; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.825T>A p.C275* | Nonsense Mutation (SNP) | VAF 17/22 reads (77%) | hotspot (GDC flag); catalogued as CM152980, COSV52759232, COSV52912941, COSV53086963; called by muse, mutect2, varscan2
- ABCC6 | c.2975G>A p.G992E | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99229505; called by muse, mutect2, varscan2
- ABCG5 | c.39G>A p.M13I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV53212821, COSV99575592; called by muse, mutect2, varscan2
- ACSBG1 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV99357749; called by muse, mutect2, varscan2
- ADAM29 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV63662611; called by muse, mutect2, varscan2
- ADAMTS20 | c.3613T>A p.F1205I | Missense Mutation (SNP) | VAF 101/126 reads (80%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.565); catalogued as COSV101166387; called by muse, mutect2, varscan2
- ADAMTS6 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 69/121 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100068581; called by muse, mutect2, varscan2
- ADAMTS6 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.643); catalogued as COSV66856688; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2402C>T p.S801F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101002036; called by muse, mutect2, varscan2
- ADCY8 | c.3469G>A p.G1157S | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99654014; called by muse, mutect2, varscan2
- ADGRB3 | c.3686G>A p.G1229E | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1254198978, COSV53233042, COSV53257692; called by muse, varscan2
- ADGRB3 | c.3737C>T p.S1246F | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV53259892; called by muse, varscan2
- ADGRE1 | c.1043C>A p.S348Y | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV51672721, COSV99165755; called by muse, mutect2, varscan2
- ADGRV1 | c.5563G>T p.A1855S | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.32); PolyPhen benign (0.292); catalogued as COSV101316411; called by muse, mutect2, varscan2
- AFG3L2 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV99302124; called by muse, mutect2, varscan2
- AGXT2 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs755905884, COSV99183882; called by muse, mutect2, varscan2
- AIRE | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99381380; called by muse, mutect2
- AK5 | c.712G>A p.D238N (on ENST00000354567 / NM_174858.3; = p.D212N on NM_012093.4) | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1019747082, COSV60982163; called by muse, mutect2, varscan2
- ALPP | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101235185; called by muse, mutect2, varscan2
- ANKRD29 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV99409280; called by muse, mutect2, varscan2
- ANKRD35 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100841837; called by muse, mutect2, varscan2
- ANO6 | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 314/404 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1297885463, COSV100263810; called by muse, mutect2, varscan2
- AP3B2 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.025); catalogued as COSV55610905; called by muse, mutect2, varscan2
- APBB1IP | c.692-1G>A p.X231_splice | Splice Site (SNP) | VAF 33/61 reads (54%) | catalogued as COSV100770916; called by muse, mutect2, varscan2
- APOB | c.9859G>A p.G3287S | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.042); catalogued as rs867491453, COSV99267561; called by muse, mutect2, varscan2
- APOB | c.9718G>A p.D3240N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769213768, COSV51944738; called by muse, mutect2, varscan2
- APOB | c.4862C>T p.S1621F | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV51940164, COSV99267469; called by muse, mutect2, varscan2
- ARHGEF15 | c.1815G>A p.M605I | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100730138; called by muse, mutect2, varscan2
- ARHGEF2 | c.773C>T p.T258I (on ENST00000361247 / NM_001162383.2; = p.T230I on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV100561119; called by muse, mutect2, varscan2
- ARHGEF40 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV100070659; called by muse, mutect2, varscan2
- ATG9B | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1187300008, COSV99874908; called by muse, mutect2, varscan2
- ATP13A3 | c.1528C>T p.L510F | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs1189310579, COSV99757574; called by muse, mutect2, varscan2
- ATP13A5 | c.2296C>T p.Q766* | Nonsense Mutation (SNP) | VAF 43/79 reads (54%) | catalogued as COSV100665653; called by muse, mutect2, varscan2
- ATP1A4 | c.1557G>C p.E519D | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100927633; called by muse, mutect2, varscan2
- ATP2B2 | c.1364C>T p.S455L (on ENST00000352432; = p.S421L on NM_001683.5) | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1198836153, COSV100660404; called by muse, mutect2, varscan2
- ATP6AP2 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV101011558; called by muse, mutect2, varscan2
- AUTS2 | c.2581C>T p.L861F | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated (0.7); PolyPhen benign (0.1); catalogued as COSV100719444; called by muse, mutect2, varscan2
- AZU1 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.06); catalogued as rs563340651, COSV52140138, COSV99297438; called by muse, mutect2, varscan2
- B3GALT6 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1360531002, CM148989, COSV99767871; called by muse, mutect2, varscan2
- B3GNT7 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV99806001; called by muse, mutect2, varscan2
- B4GAT1 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV100240367; called by muse, mutect2, varscan2
- BANK1 | c.904-1G>A p.X302_splice | Splice Site (SNP) | VAF 46/73 reads (63%) | catalogued as COSV100536758; called by muse, mutect2, varscan2
- BDNF | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100151814; called by muse, mutect2, varscan2
- BIRC3 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); catalogued as COSV99680187; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs754132810, COSV99959060; called by muse, mutect2, varscan2
- BRD2 | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs753696095, COSV66372888; called by muse, mutect2, varscan2
- BSPRY | c.863G>A p.W288* | Nonsense Mutation (SNP) | VAF 24/40 reads (60%) | catalogued as COSV99445104; called by muse, mutect2, varscan2
- C1QTNF2 | c.461G>A p.G154D (on ENST00000393975; = p.G109D on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/71 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375791963, COSV101220892; called by muse, mutect2, varscan2
- C1orf127 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100983510; called by muse, mutect2, varscan2
- C7 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as rs1056448422, COSV100496490; called by muse, mutect2, varscan2
- C8B | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100980890; called by muse, mutect2, varscan2
- CACNA2D1 | c.2407C>T p.Q803* (on ENST00000356253 / NM_001366867.1; = p.Q791* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 89/183 reads (49%) | catalogued as rs1554332740, COSV100665877, COSV100667146; called by muse, mutect2, varscan2
- CALHM2 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs751065441, COSV104393751, COSV99588798; called by muse, mutect2, varscan2
- CAMKMT | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297525051, COSV101035376; called by muse, mutect2, varscan2
- CAMSAP3 | c.2423C>T p.P808L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1269686632, COSV99351852; called by muse, mutect2, varscan2
- CAPN9 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV99681025; called by muse, mutect2, varscan2
- CAPN9 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV55239642; called by muse, mutect2, varscan2
- CARD11 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 138/288 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101210606; called by muse, mutect2, varscan2
- CCDC73 | c.1326A>T p.E442D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as COSV100068221; called by muse, mutect2, varscan2
- CCDC73 | c.1214G>A p.S405N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100068222; called by muse, mutect2, varscan2
- CD101 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99870136; called by muse, mutect2, varscan2
- CDH13 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1258821781, COSV99230219; called by muse, mutect2, varscan2
- CDHR2 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs759818454, COSV56138267, COSV56140432, COSV99991613; called by muse, mutect2, varscan2
- CEACAM5 | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 176/516 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs781873106, COSV99704137; called by muse, mutect2, varscan2
- CFAP61 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs147290599, COSV99846458; called by muse, mutect2, varscan2
- CHD8 | c.6083A>T p.H2028L (on ENST00000646647 / NM_001170629.2; = p.H1749L on NM_020920.4) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100765270; called by muse, mutect2, varscan2
- CHGB | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.056); catalogued as rs778423183, COSV66759541; called by muse, mutect2, varscan2
- CLASRP | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); catalogued as rs775057444, COSV99674106; called by muse, varscan2
- CLEC16A | c.2680C>T p.P894S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55490069; called by muse, mutect2
- CLIC4 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs747907771, COSV100978209; called by muse, mutect2, varscan2
- CNGB1 | c.1536G>A p.R512= | Splice Region (SNP) | VAF 27/41 reads (66%) | catalogued as rs376659034, COSV99208950; called by muse, mutect2, varscan2
- CNTN5 | c.3011C>T p.S1004F | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54357417; called by muse, mutect2, varscan2
- CNTNAP5 | c.1660T>C p.Y554H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.997); catalogued as COSV101444115; called by muse, mutect2, varscan2
- COL11A1 | c.4079G>A p.G1360E | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1362979459, COSV62174307; called by muse, mutect2, varscan2
- COL11A1 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.333); catalogued as COSV100617911; called by muse, mutect2, varscan2
- COL14A1 | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV52857042; called by muse, mutect2, varscan2
- COL1A2 | c.3623C>T p.P1208L | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV99800874; called by muse, mutect2, varscan2
- COL21A1 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV55152793, COSV99780011; called by muse, mutect2, varscan2
- COL5A3 | c.3527C>T p.P1176L | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV53405271, COSV53420560; called by muse, mutect2, varscan2
- COL9A1 | c.2458G>A p.G820S | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100295448; called by muse, mutect2, varscan2
- COL9A2 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101025634; called by muse, mutect2, varscan2
- COL9A3 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100673567; called by muse, mutect2, varscan2
- CPAMD8 | c.3513G>A p.G1171= (on ENST00000651564; = p.G1124= on NM_015692.5) | Splice Region (SNP) | VAF 25/54 reads (46%) | catalogued as rs1302812409, COSV101488577; called by muse, mutect2, varscan2
- CREBBP | c.6983C>T p.S2328L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as rs1567259787, COSV52115011; called by muse, mutect2, varscan2
- CSMD2 | c.9830C>T p.S3277F | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53935568; called by muse, mutect2, varscan2
- CSMD2 | c.9647C>T p.S3216F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as rs267598562, COSV99594536; called by muse, mutect2, varscan2
- CSMD2 | c.476A>G p.D159G | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs1374429327, COSV99594539; called by muse, mutect2, varscan2
- CSMD3 | c.8071+1G>A p.X2691_splice (on ENST00000297405 / NM_001363185.1; = p.X2587_splice on NM_052900.3) | Splice Site (SNP) | VAF 52/171 reads (30%) | catalogued as COSV99845850; called by muse, mutect2, varscan2
- CTAGE1 | c.1170G>A p.M390I | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV66943277; called by muse, mutect2, varscan2
- CTAGE6 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV101417876; called by muse, mutect2, varscan2
- CTXN3 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as COSV65217972, COSV65218547, COSV65218726; called by muse, mutect2, varscan2
- CUL4B | c.2494-1G>A p.X832_splice | Splice Site (SNP) | VAF 81/113 reads (72%) | catalogued as COSV60690157; called by muse, mutect2, varscan2
- CXorf58 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs753173434, COSV64858200; called by muse, mutect2, varscan2
- CYP11B1 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.329); catalogued as COSV52830232; called by muse, mutect2, varscan2
- CYP2C19 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 58/101 reads (57%) | catalogued as COSV64909569; called by muse, mutect2, varscan2
- DAPP1 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); catalogued as rs1383892303, COSV56451030; called by muse, mutect2, varscan2
- DCLK3 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 81/134 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374711533, COSV69362178; called by muse, mutect2, varscan2
- DEPTOR | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1368549626, COSV99639271; called by muse, mutect2, varscan2
- DLGAP3 | c.2416G>A p.V806M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1365376704, COSV99333109; called by muse, mutect2, varscan2
- DLL4 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs889650035, COSV99989982; called by muse, mutect2, varscan2
- DNAH17 | c.11434G>A p.E3812K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs776360838, COSV101103249; called by muse, mutect2, varscan2
- DNAH3 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs770778993, COSV99768862; called by muse, mutect2, varscan2
- DNAH5 | c.4263T>G p.S1421R | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.281); catalogued as COSV99453425; called by muse, mutect2, varscan2
- DNAH8 | c.4327G>A p.E1443K | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); catalogued as rs142959082, COSV59434250, COSV59455704; called by muse, mutect2, varscan2
- DNAH9 | c.2250G>A p.M750I | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV52346715; called by muse, mutect2, varscan2
- DNAJB4 | c.939A>T p.E313D | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV100883485; called by muse, mutect2, varscan2
- DPYSL5 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV99982063; called by muse, mutect2, varscan2
- DSCAM | c.5531C>T p.S1844L | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs775828668, COSV68020956; called by muse, mutect2, varscan2
- DSG2 | c.2168G>A p.S723N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV55200683; called by muse, mutect2, varscan2
- DYNC1LI1 | c.1143C>T p.S381= | Splice Region (SNP) | VAF 16/23 reads (70%) | catalogued as rs1188059083, COSV99818317; called by muse, mutect2, varscan2
- DZIP3 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV64313147; called by muse, mutect2, varscan2
- EIF4G3 | c.4016C>T p.T1339I | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99945407; called by muse, mutect2, varscan2
- EMSY | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749676543, COSV100596019; called by muse, mutect2, varscan2
- EPHB6 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.072); catalogued as rs1382943675, COSV63892331, COSV63893651; called by muse, mutect2, varscan2
- EPPK1 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.774); catalogued as rs1554661830, COSV101599945; called by muse, mutect2, varscan2
- ERICH3 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as rs1199533626, COSV58603692, COSV58614001; called by muse, mutect2, varscan2
- ERN2 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV99890542; called by muse, mutect2, varscan2
- ESRP2 | c.1072G>A p.V358M (on ENST00000565858 / NM_001365264.1; = p.V348M on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs1200995348, COSV99251460; called by muse, mutect2, varscan2
- ESX1 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV101006501; called by muse, mutect2, varscan2
- EXT1 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as CD1413642, COSV100984125; called by muse, mutect2, varscan2
- FABP2 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV99916986; called by muse, mutect2, varscan2
- FAM166A | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1385094251, COSV100458158; called by muse, mutect2, varscan2
- FAM171A1 | c.2413G>A p.V805I | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.258); catalogued as COSV100968499; called by muse, mutect2, varscan2
- FAM186B | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99220141; called by muse, mutect2, varscan2
- FAM221A | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV100794382; called by muse, mutect2, varscan2
- FARSB | c.299T>C p.M100T | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99918595; called by muse, mutect2, varscan2
- FAT3 | c.1967C>T p.T656I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99970348; called by muse, mutect2, varscan2
- FAT3 | c.4264G>A p.D1422N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99970356; called by muse, mutect2, varscan2
- FLG2 | c.3895C>T p.H1299Y | Missense Mutation (SNP) | VAF 133/343 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101166151; called by muse, mutect2, varscan2
- FLG2 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.271); catalogued as rs1321771272, COSV101166152; called by muse, mutect2, varscan2
- FLNC | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 122/248 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100368643; called by muse, mutect2, varscan2
- FNDC3A | c.3098C>T p.P1033L (on ENST00000492622 / NM_001079673.2; = p.P977L on NM_014923.5) | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV68133258; called by muse, mutect2, varscan2
- FRAS1 | c.4868C>T p.A1623V | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs772760584, COSV99355376; called by muse, mutect2, varscan2
- FREM2 | c.9415G>A p.E3139K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs746196338, COSV54829523; called by muse, mutect2, varscan2
- FRMD7 | c.569G>A p.R190K | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100049244; called by muse, mutect2, varscan2
- FRMPD3 | c.4499C>T p.A1500V | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as COSV99346962; called by muse, mutect2, varscan2
- FSCN3 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50001694; called by muse, mutect2, varscan2
- FUS | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs144342946; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FUT5 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.999); catalogued as rs750215709, COSV99398970; called by muse, mutect2, varscan2
- GABRB2 | c.1465C>T p.R489W (on ENST00000274547; = p.R451W on NM_000813.3) | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50907457; called by muse, mutect2, varscan2
- GABRE | c.453G>A p.W151* | Nonsense Mutation (SNP) | VAF 54/63 reads (86%) | catalogued as rs866253828, COSV100944363; called by muse, mutect2, varscan2
- GAD2 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV99393936; called by muse, mutect2, varscan2
- GCNT1 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV65058907; called by muse, mutect2, varscan2
- GFRAL | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as COSV61229115; called by muse, mutect2, varscan2
- GFRAL | c.1033C>T p.H345Y | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs753873571, COSV61231413, COSV61231877; called by muse, mutect2, varscan2
- GIMAP4 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV55432658; called by muse, mutect2, varscan2
- GLRB | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1287910151, COSV52414608; called by muse, mutect2, varscan2
- GMIP | c.2353C>T p.Q785* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99179543; called by muse, varscan2
- GPC5 | c.1578G>A p.M526I | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as rs866528463, COSV100995652, COSV65589900, COSV65631426; called by muse, mutect2, varscan2
- GPR52 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs1173137609, COSV99273669; called by muse, mutect2, varscan2
- GRAMD4 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100730619; called by muse, mutect2, varscan2
- GRHL1 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs555628494, COSV100258132; called by muse, mutect2, varscan2
- GRIA3 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 104/133 reads (78%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV52082140, COSV99991524; called by muse, mutect2, varscan2
- GRIP2 | c.3289G>A p.D1097N (on ENST00000619221; = p.D1000N on NM_001080423.4) | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs543809953, COSV99817609; called by muse, mutect2, varscan2
- GRM3 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as COSV64480557; called by muse, mutect2, varscan2
- GYS2 | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV99680170; called by muse, mutect2, varscan2
- H2BC9 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV55100180; called by muse, mutect2, varscan2
- HAPLN2 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV99661034; called by mutect2, varscan2
- HAPLN4 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868748770, COSV52269289; called by muse, mutect2, varscan2
- HERPUD2 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV100258118; called by muse, mutect2, varscan2
- HIVEP1 | c.5654C>T p.P1885L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.073); catalogued as COSV101045658, COSV65098960; called by muse, mutect2, varscan2
- HIVEP3 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs777497573, COSV99913778; called by muse, mutect2, varscan2
- HMSD | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV68817033; called by muse, mutect2, varscan2
- HNF1A | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.024); catalogued as rs1420815858, COSV99982953; called by muse, mutect2, varscan2
- IGFBP1 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as COSV99298835; called by muse, mutect2, varscan2
- IGLV2-23 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs527928402; called by muse, mutect2, varscan2
- IKZF1 | c.918G>A p.M306I | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as COSV58789572; called by muse, mutect2, varscan2
- IL18 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99737344; called by muse, mutect2, varscan2
- IL31RA | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763497; called by muse, varscan2
- INAVA | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs367914105; called by muse, varscan2
- INO80 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100732040; called by muse, mutect2, varscan2
- INPP5B | c.989C>T p.S330L (on ENST00000373023; = p.S250L on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.66); PolyPhen benign (0.177); catalogued as COSV100886598; called by muse, mutect2, varscan2
- INSRR | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as COSV63877025; called by muse, mutect2, varscan2
- INTS4 | c.1829C>T p.S610F | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV101417264; called by muse, mutect2, varscan2
- IRGC | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.299); catalogued as COSV54985568; called by muse, mutect2, varscan2
- ISM1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs1213218793, COSV99340277; called by muse, mutect2, varscan2
- ITGA11 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as rs1295990468, COSV100242123, COSV59880288; called by muse, mutect2
- ITGA9 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs1157293195, COSV99293812; called by muse, mutect2, varscan2
- ITPR1 | c.3266G>A p.S1089N (on ENST00000354582; = p.S1074N on NM_002222.7) | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as COSV100232971; called by muse, mutect2, varscan2
- JUP | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV60279347; called by muse, mutect2, varscan2
- KALRN | c.2015C>T p.S672F | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs773202936, COSV104384090, COSV99566969; called by muse, mutect2, varscan2
- KBTBD6 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); catalogued as COSV101068851; called by muse, mutect2, varscan2
- KCNA1 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101230330; called by muse, mutect2, varscan2
- KCNA10 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100871483; called by muse, mutect2, varscan2
- KCNH8 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100110918, COSV60459684; called by muse, mutect2, varscan2
- KCNK1 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64035433; called by muse, varscan2
- KIAA1841 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99694180; called by muse, mutect2, varscan2
- KIDINS220 | c.4220G>T p.S1407I | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV99876341; called by muse, mutect2, varscan2
- KIF21A | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62770181; called by muse, mutect2, varscan2
- KIF5C | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1467114015, COSV68480925; called by muse, mutect2, varscan2
- KIR2DL3 | c.529G>T p.V177F | Missense Mutation (SNP) | VAF 94/247 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.445); catalogued as COSV100668045; called by muse, mutect2, varscan2
- KIRREL3 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV101585862; called by muse, mutect2, varscan2
- KLHDC7A | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1553122963, COSV68769075; called by muse, mutect2, varscan2
- KLHL4 | c.1203G>A p.M401I | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV64139763, COSV64140213; called by muse, mutect2, varscan2
- KLK15 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs1326706289, COSV56825765; called by muse, mutect2, varscan2
- KMT5B | c.1201G>T p.V401L | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs547961826, COSV100430425, COSV58568407; called by muse, mutect2, varscan2
- KRBA1 | c.2308C>A p.P770T | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV99753069; called by muse, mutect2, varscan2
- KRTAP13-4 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.829); catalogued as rs76547537, COSV61879152; called by muse, varscan2
- LAMA3 | c.9642+1G>A p.X3214_splice (on ENST00000313654 / NM_198129.4; = p.X1605_splice on NM_000227.6) | Splice Site (SNP) | VAF 28/58 reads (48%) | catalogued as rs780861460, COSV99335707; called by muse, mutect2, varscan2
- LCK | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100288071; called by muse, mutect2, varscan2
- LDB2 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 26/44 reads (59%) | catalogued as COSV100454656; called by muse, mutect2, varscan2
- LGR4 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs768593996, COSV101004374, COSV64864450; called by muse, mutect2
- LILRB1 | c.1126G>A p.E376K (on ENST00000427581; = p.E340K on NM_006669.6) | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as COSV100207782; called by muse, mutect2, varscan2
- LMO1 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1341562548, COSV100231096; called by muse, mutect2, varscan2
- LPA | c.4085C>T p.P1362L | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as rs377407747; called by muse, mutect2, varscan2
- LRBA | c.488A>G p.N163S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100842033; called by muse, mutect2, varscan2
- LRP1B | c.1973G>A p.W658* | Nonsense Mutation (SNP) | VAF 29/89 reads (33%) | catalogued as COSV101260103; called by muse, mutect2, varscan2
- LRRC30 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as rs1296284033, COSV101274450; called by muse, mutect2, varscan2
- LRRC37A3 | c.4132C>T p.P1378S | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV100141461; called by muse, mutect2, varscan2
- LRRC8C | c.2035C>T p.L679F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100968397; called by muse, mutect2, varscan2
- LRRK2 | c.2527G>A p.V843M | Missense Mutation (SNP) | VAF 110/167 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100111024; called by muse, mutect2, varscan2
- LRRN1 | c.2075G>A p.S692N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.099); catalogued as rs1169001673, COSV100076550; called by muse, mutect2, varscan2
- MACF1 | c.21820C>T p.H7274Y (on ENST00000372915; = p.H5319Y on NM_012090.5) | Missense Mutation (SNP) | VAF 33/160 reads (21%) | catalogued as COSV99246451; called by muse, mutect2, varscan2
- MAGEC3 | c.664T>A p.F222I | Missense Mutation (SNP) | VAF 64/88 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100026007; called by muse, mutect2, varscan2
- MAML1 | c.2770C>T p.P924S | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1378851623, COSV52983734; called by muse, mutect2, varscan2
- MAML2 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101594184; called by muse, mutect2, varscan2
- MAN2A1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99811803; called by muse, mutect2, varscan2
- MAP1A | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 30/75 reads (40%) | catalogued as COSV100289148; called by muse, mutect2, varscan2
- MCOLN1 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV99900814; called by muse, mutect2, varscan2
- MDN1 | c.16310C>T p.P5437L | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101021769; called by muse, mutect2, varscan2
- MECOM | c.2543G>A p.R848Q (on ENST00000468789 / NM_001105078.4; = p.R1036Q on NM_004991.4) | Missense Mutation (SNP) | VAF 59/90 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs756700169, COSV52959825, COSV52966120; called by muse, mutect2, varscan2
- MICAL3 | c.3791C>T p.P1264L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as COSV101490955; called by muse, mutect2, varscan2
- MORC1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 189/264 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV51713955; called by muse, mutect2, varscan2
- MROH2B | c.4498G>A p.E1500K | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV101270938, COSV68186181; called by muse, mutect2, varscan2
- MS4A2 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV99627483; called by muse, mutect2, varscan2
- MTUS2 | c.2942G>A p.G981E | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as rs1266474973, COSV101462349; called by muse, mutect2, varscan2
- MUC16 | c.42040C>T p.H14014Y | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated, low confidence (0.58); PolyPhen probably damaging (0.93); catalogued as rs765270798, COSV101109359, COSV101110067; called by muse, mutect2, varscan2
- MUC16 | c.33521C>T p.S11174F | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV67490666; called by muse, mutect2, varscan2
- MUC16 | c.32243G>A p.R10748K | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.009); catalogued as COSV101200332; called by muse, mutect2
- MUC16 | c.31734G>C p.E10578D | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.719); catalogued as rs377129355, COSV67459177; called by muse, mutect2, varscan2
- MUC16 | c.17183C>T p.S5728F | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs866944888, COSV67444191, COSV67500083; called by muse, mutect2, varscan2
- MUC16 | c.11075G>A p.S3692N | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as rs1202196568, COSV101201318; called by muse, mutect2, varscan2
- MUC17 | c.2711C>T p.S904L | Missense Mutation (SNP) | VAF 338/714 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs139093882, COSV60299425; called by muse, mutect2, varscan2
- MUC3A | c.9130C>T p.Q3044* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs1256012743; called by muse, mutect2, varscan2
- MUC6 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.641); catalogued as COSV101424773, COSV70148195; called by muse, mutect2
- MYH11 | c.560A>C p.N187T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV100260076; called by muse, mutect2, varscan2
- MYH2 | c.2574G>A p.M858I | Missense Mutation (SNP) | VAF 59/91 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV55431764; called by muse, mutect2, varscan2
- MYH7 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 81/114 reads (71%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs727504416, COSV100806536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV67960428; called by muse, mutect2, varscan2
- MYH8 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101238463, COSV101238689; called by muse, mutect2, varscan2
- MYH8 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 126/216 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs762610774, COSV101238691; called by muse, mutect2, varscan2
- MYL9 | c.502A>T p.K168* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99641157; called by muse, mutect2, varscan2
- MYO16 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.725); catalogued as rs199515638, COSV99194504; called by muse, mutect2, varscan2
- MYO18B | c.6896G>A p.G2299E | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.466); catalogued as COSV59132022; called by muse, mutect2, varscan2
- MYO3B | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58695030; called by muse, mutect2, varscan2
- MYO5B | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764674526, COSV99546136; called by muse, mutect2, varscan2
- MYT1L | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67709081; called by muse, mutect2, varscan2
- NAIP | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.596); catalogued as COSV99519447; called by muse, mutect2, varscan2
- NBPF1 | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 161/579 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.139); catalogued as rs747905337, COSV55322988; called by muse, mutect2, varscan2
- NCAM2 | c.1173G>C p.K391N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV53078451, COSV99524970; called by muse, mutect2, varscan2
- NCAN | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99388161; called by muse, mutect2, varscan2
- NCK2 | c.349T>A p.F117I | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99256823; called by muse, mutect2, varscan2
- NEB | c.5064G>A p.M1688I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.899); catalogued as COSV99427220; called by muse, mutect2
- NFATC1 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53698316, COSV99501587; called by muse, mutect2, varscan2
- NFATC4 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51605150; called by muse, mutect2, varscan2
- NIPAL1 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV55006003; called by muse, mutect2, varscan2
- NLRP8 | c.2010G>A p.W670* | Nonsense Mutation (SNP) | VAF 37/81 reads (46%) | catalogued as COSV99405865; called by muse, mutect2, varscan2
- NLRP9 | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV100243359; called by muse, mutect2, varscan2
- NME8 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.091); catalogued as COSV99553773; called by muse, mutect2, varscan2
- NME8 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1044473414, COSV52253335; called by muse, mutect2, varscan2
- NOTCH2 | c.6992C>T p.A2331V | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as COSV99866543; called by muse, mutect2, varscan2
- NPHS2 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV100858206; called by muse, mutect2, varscan2
- NRXN1 | c.3311G>A p.G1104D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs376483387, COSV58443458; called by muse, mutect2, varscan2
- NUDT1 | c.119G>A p.R40Q (on ENST00000397048 / NM_198952.1; = p.R17Q on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as rs372407158; called by muse, mutect2, varscan2
- OLFM2 | c.925T>A p.Y309N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53430484, COSV99322013; called by muse, mutect2, varscan2
- OR10H2 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV100008872; called by muse, mutect2
- OR10J1 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759504026, COSV101419995; called by muse, mutect2, varscan2
- OR10Q1 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100372378; called by muse, mutect2, varscan2
- OR1B1 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100506535; called by muse, mutect2, varscan2
- OR2A4 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1459904467, COSV100199724; called by muse, mutect2
- OR2A5 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 120/247 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201237598; called by muse, mutect2
- OR2F1 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 101/299 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101231329; called by muse, mutect2, varscan2
- OR2L8 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs763873339, COSV61726091; called by muse, mutect2
- OR52E4 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100389356; called by muse, mutect2, varscan2
- OR5J2 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56620887; called by muse, mutect2, varscan2
- OR5T3 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100282921; called by muse, mutect2, varscan2
- OR8A1 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); catalogued as COSV52509068; called by muse, mutect2, varscan2
- OR8D1 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs867839009, COSV100766672; called by muse, mutect2, varscan2
- OR8G1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV58383383; called by muse, mutect2, varscan2
- PAM | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99173796; called by muse, mutect2, varscan2
- PAX1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs200118388, COSV101270376; called by muse, mutect2, varscan2
- PCDHAC1 | c.2433G>A p.M811I | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs782073530, COSV99169445; called by muse, mutect2, varscan2
- PCDHB4 | c.2041C>T p.Q681* | Nonsense Mutation (SNP) | VAF 81/139 reads (58%) | catalogued as COSV99522466; called by muse, mutect2, varscan2
- PCDHB5 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.232); catalogued as rs1554275790, COSV99169414; called by muse, mutect2, varscan2
- PCDHB5 | c.1481A>G p.N494S | Missense Mutation (SNP) | VAF 79/130 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.065); catalogued as COSV99169416; called by muse, mutect2, varscan2
- PCDHB8 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 57/84 reads (68%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.612); catalogued as rs1554280952, COSV50754677; called by muse, mutect2, varscan2
- PCED1B | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 147/190 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV71394934; called by muse, mutect2, varscan2
- PCLO | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV61665281; called by muse, mutect2, varscan2
- PDE11A | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465415051, COSV99614528; called by muse, mutect2, varscan2
- PDGFRB | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV55808738; called by muse, mutect2, varscan2
- PHC1 | c.1222C>T p.Q408* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV101418697, COSV70418877; called by muse, mutect2, varscan2
- PKHD1L1 | c.2738G>A p.G913E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs866551110, COSV65738761, COSV65751132; called by muse, mutect2, varscan2
- PKHD1L1 | c.7111G>A p.V2371I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1368753226, COSV101006742; called by muse, mutect2, varscan2
- PLCG2 | c.649-1G>A p.X217_splice | Splice Site (SNP) | VAF 33/46 reads (72%) | catalogued as COSV100842595; called by muse, mutect2, varscan2
- PNLIPRP1 | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100724508; called by mutect2, varscan2
- POF1B | c.1655G>A p.R552K | Missense Mutation (SNP) | VAF 39/50 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs1217804788, COSV99426818, COSV99427308; called by muse, mutect2, varscan2
- POM121L12 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs778343482, COSV68692644, COSV68693105; called by muse, mutect2, varscan2
- POSTN | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101123471, COSV65713447; called by muse, mutect2, varscan2
- PPARA | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV53079960; called by muse, mutect2, varscan2
- PPP4R3A | c.1318C>T p.P440S (on ENST00000554943 / NM_001366432.1; = p.P427S on NM_001284280.1) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV100466444; called by muse, mutect2, varscan2
- PPP4R3A | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs200456384, COSV100466447; called by muse, mutect2, varscan2
- PRB2 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 154/434 reads (35%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.489); catalogued as rs770261707, COSV101231445, COSV66984400; called by muse, varscan2
- PRPF8 | c.4354C>T p.P1452S | Missense Mutation (SNP) | VAF 62/72 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV59268952; called by muse, mutect2, varscan2
- PRPH | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); catalogued as rs1283800952, COSV99142055; called by muse, mutect2, varscan2
- PRPH | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV99142058; called by muse, mutect2, varscan2
- PRRC2C | c.7910C>T p.P2637L (on ENST00000367742; = p.P2635L on NM_015172.4) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs771997077, COSV100145923; called by muse, varscan2
- PSAPL1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs1006844615, COSV100040691; called by muse, mutect2, varscan2
- PSME2 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as COSV99246472; called by muse, mutect2, varscan2
- PTOV1 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); catalogued as COSV99681989; called by muse, mutect2
- PYDC1 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.183); catalogued as COSV100265473; called by muse, mutect2, varscan2
- RAB37 | c.340A>G p.N114D (on ENST00000392613 / NM_001006638.3; = p.N107D on NM_175738.5) | Missense Mutation (SNP) | VAF 62/99 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100463564; called by muse, mutect2, varscan2
- RABEP2 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as rs1400721271, COSV100707141; called by muse, mutect2, varscan2
- RAC2 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV99969637; called by muse, mutect2, varscan2
- RALGAPA1 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs778054647, COSV99355891; called by muse, mutect2, varscan2
- RALGAPA1 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs749619849, COSV99355690, COSV99355893; called by muse, mutect2, varscan2
- RBM47 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV99921541; called by muse, mutect2, varscan2
- REC114 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV100461782; called by muse, mutect2
- RELN | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV100634719; called by muse, mutect2, varscan2
- RERE | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as rs374993545; called by muse, mutect2, varscan2
- RFPL1 | c.753G>A p.M251I | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV100585885; called by muse, mutect2, varscan2
- RFX6 | c.2485C>T p.R829C | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs766770911, COSV60587555; called by muse, mutect2, varscan2
- RGL3 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.998); catalogued as rs770464221, COSV100993095; called by muse, mutect2, varscan2
- RNF217 | c.1570C>T p.P524S (on ENST00000521654 / NM_001286398.2; = p.S270F on NM_152553.5) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); catalogued as COSV99255319; called by muse, mutect2, varscan2
- RP1 | c.3661C>T p.P1221S | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV55124669; called by muse, mutect2, varscan2
- RPE65 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as CM983756, COSV99254246; called by muse, mutect2, varscan2
- RPS6KB2 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100412361; called by muse, mutect2, varscan2
- RTN3 | c.1426C>T p.H476Y (on ENST00000377819 / NM_001265589.2; = p.H457Y on NM_201428.3) | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs867331805, COSV100380324; called by muse, mutect2, varscan2
- RTTN | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99733666; called by muse, mutect2, varscan2
- RUNX1T1 | c.1238C>T p.S413F (on ENST00000265814 / NM_001198628.1; = p.S386F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.458); catalogued as COSV99754438; called by muse, mutect2, varscan2
- S100A7L2 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100906929; called by muse, mutect2, varscan2
- SCN1A | c.5380G>A p.E1794K (on ENST00000303395 / NM_001202435.3; = p.E1783K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57670818; called by muse, mutect2, varscan2
- SCN1A | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV100321821, COSV57675094; called by muse, mutect2, varscan2
- SCN2A | c.5320G>A p.V1774I | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.997); catalogued as COSV99333184; called by muse, mutect2, varscan2
- SCN9A | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV57600921; called by muse, mutect2, varscan2
- SCUBE2 | c.2806G>A p.E936K (on ENST00000649792 / NM_001367977.2; = p.E879K on NM_020974.3) | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100496898; called by muse, mutect2, varscan2
- SEMA4A | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100740719; called by muse, mutect2, varscan2
- SEMA6D | c.1800G>A p.M600I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs759922413, COSV100317504; called by muse, mutect2, varscan2
- SERINC2 | c.451C>T p.P151S (on ENST00000373709 / NM_178865.5; = p.P155S on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101037107; called by muse, mutect2, varscan2
- SERPINB13 | c.602T>G p.F201C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99501244; called by muse, mutect2, varscan2
- SERPINB13 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs139404423; called by muse, mutect2, varscan2
- SETDB2 | c.1516dup p.M506Nfs*14 | Frame Shift Ins (INS) | VAF 24/58 reads (41%) | catalogued as rs768645211; called by mutect2, varscan2
- SFTA2 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.029); catalogued as rs150107046; called by muse, mutect2, varscan2
- SHPK | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs200632887, COSV99843996; called by muse, mutect2, varscan2
- SIGLEC1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs376584803; called by muse, mutect2, varscan2
- SIGLEC10 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV100219391; called by muse, mutect2, varscan2
- SLA2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs372541692, COSV53409940; called by muse, mutect2, varscan2
- SLC17A4 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.036); catalogued as COSV100930660; called by muse, mutect2, varscan2
- SLC22A14 | c.725T>C p.F242S | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99828339; called by muse, mutect2, varscan2
- SLC38A1 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 28/514 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs201587500, COSV67064343; called by muse, mutect2
- SLC39A2 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs759621913, COSV100068698; called by muse, mutect2, varscan2
- SLC9C2 | c.2546A>C p.N849T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as COSV100876979; called by muse, mutect2, varscan2
- SLCO1B3 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as rs762106680, COSV53941068; called by muse, mutect2, varscan2
- SLIT1 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as rs1392681464, COSV56592193; called by muse, mutect2, varscan2
- SLIT1 | c.414G>A p.L138= | Splice Region (SNP) | VAF 11/25 reads (44%) | catalogued as rs1336444524, COSV99822115; called by muse, mutect2, varscan2
- SMOC1 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.96); catalogued as COSV100734786; called by muse, mutect2, varscan2
- SNX14 | c.2413C>T p.P805S (on ENST00000314673 / NM_001350535.1; = p.P752S on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.743); catalogued as COSV100121741; called by muse, mutect2, varscan2
- SNX25 | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1277281704, COSV99253378; called by muse, mutect2, varscan2
- SPATA13 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV101173173; called by muse, mutect2, varscan2
- SPATA31E1 | c.1198A>T p.I400F | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as COSV100350977; called by muse, mutect2, varscan2
- SPON1 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.817); catalogued as rs1554941709, COSV100116565; called by muse, mutect2
- SPRR3 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV99768747; called by muse, varscan2
- SPTBN5 | c.3583G>A p.V1195I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV100312094; called by muse, mutect2, varscan2
- STARD6 | c.190T>A p.F64I | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.478); catalogued as COSV100323559; called by muse, mutect2, varscan2
- STK31 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.069); catalogued as COSV100669653; called by muse, mutect2, varscan2
- SURF4 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs181190300; called by muse, mutect2, varscan2
- SYCP2 | c.3413C>T p.S1138L | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs755198324, COSV62772554; called by muse, mutect2, varscan2
- SYNGAP1 | c.476T>G p.I159S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99538925; called by muse, mutect2, varscan2
- TAF1L | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 76/116 reads (66%) | catalogued as COSV99645319; called by muse, mutect2, varscan2
- TARS3 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as rs764890224, COSV60109317; called by muse, mutect2, varscan2
- TBC1D1 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 60/92 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV99792052; called by muse, mutect2, varscan2
- TBX18 | c.1520C>A p.A507D | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.858); catalogued as rs1197383170, COSV100858569; called by muse, mutect2, varscan2
- TCHHL1 | c.2369C>T p.S790F | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV100916599; called by muse, mutect2, varscan2
- TDRD5 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99677010; called by muse, mutect2, varscan2
- TEAD3 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV100132615; called by muse, mutect2, varscan2
- TEAD3 | c.204C>T p.G68= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as rs1298317490, COSV100132617; called by muse, mutect2, varscan2
- TENM4 | c.8170G>A p.E2724K | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99572869; called by muse, mutect2, varscan2
- TESPA1 | c.1206G>A p.W402* (on ENST00000316577 / NM_001098815.3; = p.W264* on NM_014796.2 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 44/77 reads (57%) | catalogued as rs1413930877, COSV100345580; called by muse, mutect2, varscan2
- TET2 | c.3038C>T p.P1013L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99484512; called by muse, mutect2, varscan2
- TGM6 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99172601; called by muse, mutect2, varscan2
- TGM7 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71773242; called by muse, mutect2, varscan2
- THOP1 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as rs1198914511, COSV100310765; called by muse, mutect2, varscan2
- THSD7B | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 71/216 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.091); catalogued as COSV99757455; called by muse, mutect2, varscan2
- THSD7B | c.3848G>A p.G1283E (on ENST00000272643; = p.G1281E on NM_001316349.2) | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.36); PolyPhen probably damaging (1); catalogued as rs1271824802, COSV99757458; called by muse, mutect2, varscan2
- TIAM1 | c.2939A>C p.E980A | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV99738409; called by muse, mutect2, varscan2
- TIAM2 | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as rs1277946669, COSV99265936; called by muse, mutect2, varscan2
- TLE6 | c.931G>A p.V311M (on ENST00000246112 / NM_001143986.2; = p.V188M on NM_024760.3) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866691522, COSV99858474; called by muse, mutect2, varscan2
- TMCC3 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 77/117 reads (66%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.953); catalogued as COSV54153638, COSV99705648; called by muse, mutect2, varscan2
- TNFRSF21 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV99730161; called by muse, mutect2, varscan2
- TPCN2 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1461641063, COSV99593891; called by muse, mutect2, varscan2
- TPK1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100766043; called by muse, mutect2, varscan2
- TRAPPC9 | c.1937C>T p.T646M | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs557827787, COSV101228445; called by muse, mutect2, varscan2
- TRIM56 | c.2068G>A p.G690S | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100047704; called by muse, mutect2, varscan2
- TRIP12 | c.3718C>T p.P1240S | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as rs1278092812, COSV99390858; called by muse, mutect2, varscan2
- TRIP4 | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99974890; called by muse, mutect2
- TRPM2 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100309263; called by muse, mutect2, varscan2
- TSEN34 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV55473960; called by muse, mutect2, varscan2
- TTC17 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV99235905; called by muse, mutect2, varscan2
- TTC7A | c.1170G>T p.L390F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99766904; called by muse, mutect2, varscan2
- TTN | c.77818G>A p.D25940N (on ENST00000591111; = p.D18516N on NM_003319.4) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | PolyPhen benign (0.189); catalogued as COSV60032068; called by muse, mutect2, varscan2
- TTN | c.45764C>T p.T15255I (on ENST00000591111; = p.T7831I on NM_003319.4) | Missense Mutation (SNP) | VAF 63/172 reads (37%) | PolyPhen probably damaging (0.998); catalogued as COSV100627065; called by muse, mutect2, varscan2
- TTN | c.20975G>A p.G6992E (on ENST00000591111; = p.G6065E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | PolyPhen probably damaging (0.993); catalogued as COSV100627067, COSV59888248; called by muse, mutect2, varscan2
- TTN | c.9671G>A p.R3224K (on ENST00000591111; = p.R3178K on NM_003319.4) | Missense Mutation (SNP) | VAF 34/120 reads (28%) | PolyPhen benign (0.001); catalogued as COSV100627069; called by muse, mutect2, varscan2
- UBQLNL | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV100975439; called by muse, mutect2, varscan2
- UBR4 | c.10592C>T p.P3531L | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100921674; called by muse, mutect2, varscan2
- ULK2 | c.2947C>T p.Q983* | Nonsense Mutation (SNP) | VAF 28/39 reads (72%) | catalogued as COSV64443889; called by muse, mutect2, varscan2
- UNC79 | c.3193G>A p.E1065K (on ENST00000393151 / NM_001346218.2; = p.E888K on NM_020818.5) | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56379107, COSV56391667; called by muse, mutect2, varscan2
- USP28 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as rs539823079, COSV99136457; called by muse, mutect2, varscan2
- USP42 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV100084843; called by muse, mutect2, varscan2
- USP6 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as COSV51496617; called by muse, mutect2
- VAT1L | c.791G>A p.S264N | Missense Mutation (SNP) | VAF 59/87 reads (68%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100214078; called by muse, mutect2, varscan2
- VPS37A | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs1483883258, COSV100246659; called by muse, mutect2, varscan2
- VWA8 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99864962; called by muse, mutect2, varscan2
- WDR36 | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101551002; called by muse, mutect2, varscan2
- WNT8A | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs762283369, COSV100843088; called by muse, mutect2, varscan2
- XDH | c.1537C>T p.L513F | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1180603379, COSV101052443; called by muse, mutect2, varscan2
- XIRP2 | c.2425G>A p.E809K (on ENST00000628543; = p.E984K on NM_152381.6) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753832931, COSV54688281; called by muse, mutect2, varscan2
- XKR3 | c.965G>A p.W322* | Nonsense Mutation (SNP) | VAF 23/107 reads (21%) | catalogued as COSV58887594; called by muse, mutect2
- YY1AP1 | c.872C>T p.S291F (on ENST00000295566 / NM_139118.2; = p.S214F on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99804590; called by muse, mutect2, varscan2
- ZBED9 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV71729208; called by muse, mutect2, varscan2
- ZBTB16 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs145635689, COSV100252307; called by muse, mutect2, varscan2
- ZFHX4 | c.6916C>T p.R2306* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as rs1274336018, COSV50749799; called by muse, mutect2, varscan2
- ZFP90 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV68050930; called by muse, mutect2, varscan2
- ZFPM2 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV68288214; called by muse, mutect2, varscan2
- ZNF254 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV100741756; called by muse, mutect2, varscan2
- ZNF280A | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs371462360; called by muse, mutect2, varscan2
- ZNF284 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.882); catalogued as rs776834810, COSV69690713; called by muse, mutect2, varscan2
- ZNF287 | c.1522T>C p.Y508H | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101209426; called by muse, mutect2, varscan2
- ZNF324B | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.335); catalogued as rs767436358, COSV100351780; called by muse, mutect2
- ZNF721 | c.1027C>T p.H343Y (on ENST00000338977; = p.H355Y on NM_133474.4) | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100167740, COSV59093323; called by muse, mutect2, varscan2
- ZNF780B | c.1709C>T p.S570L | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.114); catalogued as rs750125813, COSV55462752, COSV55467159; called by muse, mutect2, varscan2
- ZNF804A | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1291420047, COSV100169873; called by muse, mutect2, varscan2
- ZNF804A | c.2644C>T p.H882Y | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100166886, COSV56454265; called by muse, mutect2, varscan2
- ZNF835 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs540450261, COSV73379456; called by muse, mutect2, varscan2
- ZNF839 | c.1354G>A p.E452K (on ENST00000558850 / NM_001267827.1; = p.E568K on NM_018335.5) | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as rs773196435, COSV99216405; called by muse, mutect2, varscan2
- ZP2 | c.1664C>T p.S555F | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99559705, COSV99559782; called by muse, mutect2, varscan2
- GAGE2E | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 90/2480 reads (4%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); called by muse, mutect2
- IGHG2 | c.393G>A p.M131I | Missense Mutation (SNP) | VAF 72/124 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PDE4DIP | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- PRAMEF18 | c.728G>C p.C243S | Missense Mutation (SNP) | VAF 57/504 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SF3A1 | c.263del p.D88Afs*49 | Frame Shift Del (DEL) | VAF 28/143 reads (20%) | called by mutect2, pindel*, varscan2
- TNFRSF4 | c.370+1_370+3del p.X124_splice | Splice Site (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- ABCA7 | c.2091C>T p.F697= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs1383190114, COSV99566547; called by muse, mutect2, varscan2
- ABCB8 | c.222C>T p.L74= (on ENST00000297504 / NM_001282291.2; = p.L57= on NM_007188.5) | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV99874909; called by muse, mutect2, varscan2
- ABCC9 | c.1149C>T p.L383= | Silent (SNP) | VAF 48/141 reads (34%) | catalogued as rs1470456973, COSV99686970; called by muse, mutect2, varscan2
- AC134980.2 | c.786C>T p.F262= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs769895963, COSV60907280, COSV60908530; called by mutect2, varscan2
- ADAM22 | c.1083G>A p.G361= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as rs1335196894, COSV99718076; called by muse, mutect2, varscan2
- ADAM7 | c.1245G>A p.E415= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV99444887; called by muse, mutect2, varscan2
- ADAMTS1 | c.2667T>C p.A889= | Silent (SNP) | VAF 49/118 reads (42%) | catalogued as COSV99536467; called by muse, mutect2, varscan2
- ADAMTS10 | c.2646G>A p.E882= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV99547356; called by muse, mutect2, varscan2
- ADAMTS15 | c.2094C>T p.F698= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs267602783, COSV54503735; called by muse, mutect2, varscan2
- ADAR | c.1971C>T p.F657= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV99426628; called by muse, mutect2, varscan2
- ADARB1 | c.426C>T p.F142= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs758262178, COSV62349912; called by muse, mutect2, varscan2
- ADGRV1 | c.1723T>C p.L575= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV101316410; called by muse, mutect2, varscan2
- AFM | c.1203C>T p.F401= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as rs867638688, COSV99889151; called by muse, mutect2, varscan2
- AGR3 | c.321G>A p.K107= | Silent (SNP) | VAF 62/137 reads (45%) | catalogued as COSV100124073, COSV60037880; called by muse, mutect2, varscan2
- AHSP | c.297G>A p.P99= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs369281662; called by muse, mutect2, varscan2
- AKAP6 | c.5091C>T p.L1697= | Silent (SNP) | VAF 51/73 reads (70%) | catalogued as COSV55233101; called by muse, mutect2, varscan2
- AKR1C3 | c.690G>A p.P230= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs1333812373, COSV65910110; called by muse, mutect2
- ALDH3B2 | c.900C>T p.T300= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100824112; called by muse, mutect2, varscan2
- ANKRD35 | c.2430G>A p.L810= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100841838; called by muse, mutect2, varscan2
- ANTXR1 | c.933C>T p.I311= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100362989; called by muse, mutect2, varscan2
- APOA5 | c.567G>A p.E189= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99911467; called by muse, mutect2, varscan2
- ASAP2 | c.1728C>T p.I576= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV55629332; called by muse, mutect2, varscan2
- ATP2B3 | c.2178G>A p.E726= | Silent (SNP) | VAF 23/33 reads (70%) | catalogued as COSV99685631; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1404C>T p.F468= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV52269016; called by muse, mutect2, varscan2
- BARX2 | c.228C>T p.I76= | Silent (SNP) | VAF 90/244 reads (37%) | catalogued as COSV99858991; called by muse, mutect2, varscan2
- BLM | c.4107C>T p.S1369= | Silent (SNP) | VAF 46/117 reads (39%) | catalogued as COSV100757316; called by muse, mutect2, varscan2
- BMP10 | c.291C>T p.T97= | Silent (SNP) | VAF 62/159 reads (39%) | catalogued as COSV99770581; called by muse, mutect2, varscan2
- BRD1 | c.1266C>T p.S422= | Silent (SNP) | VAF 89/213 reads (42%) | catalogued as COSV99350214; called by muse, mutect2, varscan2
- BTBD9 | c.534C>T p.F178= | Silent (SNP) | VAF 64/153 reads (42%) | catalogued as COSV100022613; called by muse, mutect2, varscan2
- C2orf16 | c.2067G>A p.V689= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as rs766218324, COSV100820968; called by muse, mutect2, varscan2
- C7orf57 | c.162C>T p.N54= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV100817322; called by muse, mutect2, varscan2
- C7orf57 | c.163C>T p.L55= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as rs769546871, COSV62363175; called by muse, mutect2, varscan2
- CA1 | c.738C>T p.N246= | Silent (SNP) | VAF 52/107 reads (49%) | catalogued as rs756681346, COSV99810170, COSV99810325; called by muse, mutect2, varscan2
- CACNA1H | c.1845G>A p.T615= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs776887979, COSV61989774; called by muse, mutect2, varscan2
- CACNA2D3 | c.3219C>T p.L1073= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV99876619; called by muse, mutect2, varscan2
- CAMKV | c.546G>A p.G182= | Silent (SNP) | VAF 21/28 reads (75%) | catalogued as COSV56556472; called by muse, mutect2, varscan2
- CATSPER4 | c.483C>T p.F161= | Silent (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2
- CCKAR | c.1286G>A p.*429= | Silent (SNP) | VAF 51/99 reads (52%) | catalogued as COSV55161572; called by muse, mutect2, varscan2
- CCRL2 | c.1008A>G p.E336= | Silent (SNP) | VAF 56/88 reads (64%) | catalogued as COSV100645093; called by muse, mutect2, varscan2
- CD163L1 | c.3087C>T p.I1029= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV58019997; called by muse, mutect2, varscan2
- CD163L1 | c.1377C>T p.F459= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV100550601; called by muse, mutect2, varscan2
- CD163L1 | c.831G>A p.L277= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV58018853; called by muse, mutect2, varscan2
- CD177 | c.1137C>T p.F379= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as COSV100946061; called by muse, mutect2, varscan2
- CD33 | c.522C>T p.P174= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs1189704947, COSV99220738; called by muse, mutect2, varscan2
- CD6 | c.792C>T p.S264= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100533240; called by muse, mutect2, varscan2
- CDH19 | c.1362C>T p.I454= | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as rs1487852201, COSV100052194; called by muse, mutect2, varscan2
- CDH20 | c.348C>T p.I116= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99406421; called by muse, mutect2, varscan2
- CDHR3 | c.666C>T p.L222= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs1162264398, COSV100488810; called by muse, mutect2, varscan2
- CEP126 | c.909C>T p.F303= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs1431586511, COSV99681377; called by muse, mutect2
- CHD8 | c.6084C>T p.H2028= (on ENST00000646647 / NM_001170629.2; = p.H1749= on NM_020920.4) | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs754552862, COSV100765375; called by mutect2, varscan2
- CHP2 | c.183C>T p.P61= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100270080, COSV55650926; called by muse, mutect2, varscan2
- CLDN17 | c.75C>T p.T25= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV54523916, COSV99729399; called by muse, mutect2, varscan2
- CLEC6A | c.75G>A p.G25= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs765459776, COSV101165705; called by muse, mutect2, varscan2
- CLN3 | c.819C>T p.F273= (on ENST00000360019 / NM_001286104.2; = p.F297= on NM_000086.2) | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV61104957; called by muse, mutect2, varscan2
- COL11A1 | c.5130C>T p.F1710= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV100617909; called by muse, mutect2, varscan2
- COL4A3 | c.120C>T p.F40= | Silent (SNP) | VAF 70/234 reads (30%) | catalogued as COSV67418080; called by muse, mutect2, varscan2
- CRISP2 | c.207G>A p.T69= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs747699334, COSV59254852; called by muse, mutect2, varscan2
- CRYBG1 | c.1948C>T p.L650= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100954610; called by muse, mutect2, varscan2
- CRYBG2 | c.4206G>A p.T1402= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs756503684, COSV100366421, COSV57484976; called by muse, mutect2, varscan2
- CSMD2 | c.8181C>T p.I2727= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99590390; called by muse, mutect2, varscan2
- CYP2C9 | c.513C>T p.G171= | Silent (SNP) | VAF 109/171 reads (64%) | catalogued as COSV99583138; called by muse, mutect2, varscan2
- CYP4F22 | c.759C>T p.F253= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV54106674; called by muse, mutect2, varscan2
- CYP4F8 | c.195C>T p.G65= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV100358215; called by muse, mutect2, varscan2
- CYTIP | c.885G>A p.R295= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV99938901; called by muse, mutect2, varscan2
- DAAM1 | c.3090C>T p.S1030= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs145721737; called by muse, mutect2, varscan2
- DCC | c.213G>A p.V71= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV59103288; called by muse, mutect2, varscan2
- DCDC1 | c.1710G>A p.K570= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs764131540, COSV100664102; called by muse, mutect2, varscan2
- DNAH1 | c.717C>T p.F239= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs1234765193, COSV101326910; called by muse, mutect2, varscan2
- DPY19L1 | c.525C>T p.F175= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100204942; called by muse, mutect2, varscan2
- EDF1 | c.396C>T p.L132= | Silent (SNP) | VAF 89/145 reads (61%) | catalogued as COSV99808242; called by muse, mutect2, varscan2
- EHD3 | c.474C>T p.L158= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV100434845; called by muse, mutect2, varscan2
- ELAPOR1 | c.498C>T p.I166= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs766376821, COSV64045566; called by muse, mutect2, varscan2
- ENPP7 | c.765G>A p.R255= | Silent (SNP) | VAF 48/83 reads (58%) | catalogued as COSV100093663; called by muse, mutect2, varscan2
- ENTHD1 | c.1068C>T p.F356= | Silent (SNP) | VAF 42/97 reads (43%) | catalogued as COSV57319144; called by muse, mutect2, varscan2
- EPHA6 | c.609G>A p.R203= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as rs1166185432, COSV67576163; called by muse, mutect2, varscan2
- EPPK1 | c.5016C>T p.I1672= | Silent (SNP) | VAF 55/150 reads (37%) | catalogued as rs375624528; called by muse, mutect2
- FANCA | c.3483G>A p.T1161= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as rs768306527, COSV59797275, COSV99981252; called by muse, mutect2, varscan2
- FFAR3 | c.75C>T p.F25= | Silent (SNP) | VAF 31/178 reads (17%) | catalogued as rs1213569959, COSV59909816; called by muse, varscan2
- FRMD1 | c.12C>T p.P4= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs1205069414, COSV99350080; called by muse, mutect2, varscan2
- FRY | c.4881C>T p.L1627= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs267603801, COSV66565757; called by muse, mutect2, varscan2
- FUT9 | c.54C>T p.I18= | Silent (SNP) | VAF 57/148 reads (39%) | catalogued as COSV100134200; called by muse, mutect2, varscan2
- GABRD | c.1095C>T p.L365= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV101059568; called by muse, mutect2, varscan2
- GHSR | c.666C>T p.F222= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV99577185; called by muse, mutect2, varscan2
- GIMAP2 | c.856C>T p.L286= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs868749339, COSV99785502; called by muse, mutect2, varscan2
- GMIP | c.2352C>T p.S784= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99179545; called by muse, mutect2, varscan2
- GPA33 | c.444C>T p.I148= | Silent (SNP) | VAF 47/129 reads (36%) | catalogued as rs778368595, COSV63302474; called by muse, mutect2, varscan2
- GPRIN3 | c.1497G>A p.T499= | Silent (SNP) | VAF 74/118 reads (63%) | catalogued as rs780712548, COSV100310961; called by muse, mutect2, varscan2
- GRAMD1B | c.741C>T p.Y247= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100455163; called by muse, mutect2, varscan2
- GRAMD1B | c.1143C>T p.F381= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs1330603072; called by muse, mutect2, varscan2
- GRAMD4 | c.855C>T p.P285= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as rs766445397, COSV100730620; called by muse, mutect2, varscan2
- GRIN2A | c.2814G>A p.K938= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as COSV58032191; called by muse, mutect2, varscan2
- HAO2 | c.141C>T p.L47= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV100378246; called by muse, mutect2, varscan2
- HDGFL2 | c.156C>T p.F52= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV100012416; called by muse, mutect2, varscan2
- HECW1 | c.435C>T p.I145= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as rs746181473, COSV67836476; called by muse, mutect2, varscan2
- HNF1A | c.1683G>A p.Q561= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs1380283827, COSV99982952; called by muse, mutect2, varscan2
- HTR1A | c.390C>T p.I130= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV60502710; called by muse, mutect2, varscan2
- IDO1 | c.123C>T p.F41= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV99503589; called by muse, mutect2, varscan2
- IGKV1-16 | c.51C>T p.F17= | Silent (SNP) | VAF 58/172 reads (34%) | called by muse, mutect2, varscan2
- IGSF9B | c.552G>A p.G184= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100318313; called by muse, mutect2, varscan2
- IL31RA | c.234G>A p.K78= | Silent (SNP) | VAF 30/50 reads (60%) | catalogued as rs545688301, COSV99763502; called by muse, varscan2
- INO80 | c.756C>T p.A252= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100732039; called by muse, mutect2, varscan2
- ITGB2 | c.177C>T p.S59= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs1450635766, COSV100186106; called by muse, mutect2, varscan2
- KCNK1 | c.723C>T p.F241= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV64035270; called by muse, varscan2
- KCNS3 | c.561C>T p.I187= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1221716261, COSV58408871; called by muse, mutect2, varscan2
- KDM5A | c.4449C>T p.I1483= | Silent (SNP) | VAF 85/262 reads (32%) | catalogued as COSV101239040; called by muse, mutect2, varscan2
- KLHL4 | c.1095G>A p.G365= | Silent (SNP) | VAF 65/80 reads (81%) | catalogued as COSV100910121; called by muse, mutect2, varscan2
- KLK5 | c.330G>A p.R110= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100307192; called by muse, mutect2, varscan2
- KMT2C | c.5712C>T p.T1904= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV100075954; called by muse, mutect2, varscan2
- LRRC4B | c.756C>T p.L252= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100976023; called by muse, mutect2, varscan2
- LRRN2 | c.900C>T p.S300= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV100912938; called by muse, mutect2, varscan2
- LRTM1 | c.588G>A p.E196= | Silent (SNP) | VAF 53/81 reads (65%) | catalogued as COSV99836198; called by muse, mutect2, varscan2
- LY6G5B | c.447C>T p.F149= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV101020852; called by muse, mutect2, varscan2
- MACF1 | c.19002C>T p.F6334= (on ENST00000372915; = p.F4379= on NM_012090.5) | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as COSV99246448; called by muse, mutect2, varscan2
- MACROD1 | c.645C>T p.G215= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV99735982; called by muse, mutect2, varscan2
- MECP2 | c.1203C>T p.S401= | Silent (SNP) | VAF 46/63 reads (73%) | catalogued as rs782230851, COSV100318458; ClinVar: likely benign; called by muse, mutect2, varscan2
- MFHAS1 | c.1167C>T p.I389= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs1264087900, COSV99359886; called by muse, mutect2, varscan2
- MIPEP | c.1425C>T p.P475= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as rs778711223, COSV101193227; called by muse, mutect2, varscan2
- MPP7 | c.1143G>A p.L381= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV100516774; called by muse, mutect2, varscan2
- MTOR | c.4887C>T p.I1629= | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as rs186504696, COSV63868499; called by muse, mutect2, varscan2
- MUC16 | c.37995C>T p.I12665= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV101201313; called by muse, mutect2, varscan2
- MUC16 | c.37596C>T p.S12532= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV67466220; called by muse, mutect2, varscan2
- MUC16 | c.1911C>G p.S637= | Silent (SNP) | VAF 49/114 reads (43%) | catalogued as COSV101201319, COSV67495012; called by muse, mutect2, varscan2
- MYBPC3 | c.2463G>A p.L821= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV99920919; called by muse, mutect2, varscan2
- MYH4 | c.1470G>A p.Q490= | Silent (SNP) | VAF 68/109 reads (62%) | catalogued as rs574904346, COSV99702082; called by muse, mutect2, varscan2
- MYO16 | c.1449G>A p.Q483= | Silent (SNP) | VAF 59/211 reads (28%) | catalogued as COSV99194503; called by muse, mutect2, varscan2
- MYO18B | c.1375C>T p.L459= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV100124956; called by muse, mutect2
- NANOG | c.735G>A p.E245= | Silent (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- NCAM1 | c.39C>T p.F13= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs1555063061, COSV101207614; called by muse, mutect2, varscan2
- NCKAP1L | c.1332C>T p.I444= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as rs866215180, COSV53206674; called by muse, mutect2, varscan2
- NEO1 | c.669G>T p.V223= | Silent (SNP) | VAF 50/129 reads (39%) | catalogued as COSV99982705; called by muse, mutect2, varscan2
- NLRC4 | c.1468C>T p.L490= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV100707499; called by muse, mutect2, varscan2
- NMS | c.333G>A p.Q111= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100966645; called by muse, mutect2, varscan2
- NRXN1 | c.1470C>T p.F490= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV100456647, COSV58458612; called by muse, mutect2, varscan2
- NRXN3 | c.1452C>T p.I484= (on ENST00000335750 / NM_001330195.2; = p.I111= on NM_004796.6) | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as rs762162816, COSV100208251; called by muse, mutect2, varscan2
- NRXN3 | c.1590G>A p.V530= (on ENST00000335750 / NM_001330195.2; = p.V157= on NM_004796.6) | Silent (SNP) | VAF 48/72 reads (67%) | catalogued as COSV100208252, COSV59795661; called by muse, mutect2, varscan2
- NSD1 | c.6924C>T p.S2308= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV61771559, COSV61780371; called by muse, mutect2, varscan2
- NSD3 | c.3261C>T p.I1087= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV100395680; called by muse, mutect2, varscan2
- NYNRIN | c.3825C>T p.L1275= | Silent (SNP) | VAF 40/70 reads (57%) | catalogued as rs780717857, COSV66841928; called by muse, mutect2, varscan2
- OPLAH | c.3270C>T p.I1090= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1554757920, COSV101470904; called by muse, mutect2, varscan2
- OR10H2 | c.213C>T p.I71= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV59945592; called by muse, mutect2
- OR10J3 | c.423C>T p.A141= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs1460732959, COSV100171866; called by muse, mutect2, varscan2
- OR14K1 | c.486C>T p.F162= | Silent (SNP) | VAF 56/165 reads (34%) | catalogued as rs377663361, COSV99032176; called by muse, mutect2, varscan2
- OR1F1 | c.627C>T p.T209= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs1567207293, COSV58961669; called by muse, mutect2, varscan2
- OR51B2 | c.324G>A p.V108= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs1399625228, COSV60917806; called by muse, mutect2, varscan2
- OR52N2 | c.582C>T p.F194= | Silent (SNP) | VAF 87/232 reads (38%) | catalogued as COSV57677081; called by muse, mutect2, varscan2
- OR5B12 | c.795C>T p.F265= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV56904364, COSV56907044; called by muse, mutect2, varscan2
- OR5M10 | c.324G>A p.V108= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV73242374, COSV73242378; called by muse, mutect2, varscan2
- OR6K2 | c.621G>A p.E207= | Silent (SNP) | VAF 47/122 reads (39%) | catalogued as COSV100656878; called by muse, mutect2, varscan2
- OR6S1 | c.237C>T p.I79= | Silent (SNP) | VAF 44/84 reads (52%) | catalogued as COSV57839320; called by muse, mutect2, varscan2
- OR6T1 | c.192G>A p.R64= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV58309392; called by muse, mutect2, varscan2
- OR8G5 | c.405C>T p.I135= | Silent (SNP) | VAF 62/165 reads (38%) | catalogued as COSV58380357; called by muse, mutect2, varscan2
- OR8H2 | c.891G>A p.V297= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as rs267602990, COSV57945515; called by muse, mutect2, varscan2
- OTOGL | c.4992C>T p.I1664= (on ENST00000547103; = p.I1655= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 70/124 reads (56%) | catalogued as COSV100087804, COSV54015379; called by muse, mutect2, varscan2
- PAM | c.153T>C p.P51= | Silent (SNP) | VAF 49/90 reads (54%) | catalogued as rs200231533, COSV99173794; called by muse, mutect2, varscan2
- PCDH18 | c.2883G>A p.Q961= | Silent (SNP) | VAF 54/105 reads (51%) | catalogued as COSV100787486, COSV61272814; called by muse, mutect2, varscan2
- PCDHB3 | c.1377C>T p.F459= | Silent (SNP) | VAF 97/164 reads (59%) | catalogued as COSV50568585; called by muse, mutect2, varscan2
- PCLO | c.6168G>A p.R2056= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as COSV61660129; called by muse, mutect2, varscan2
- PCNX1 | c.4398C>A p.I1466= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV99457003; called by muse, mutect2, varscan2
- PDZD8 | c.1453T>C p.L485= | Silent (SNP) | VAF 81/127 reads (64%) | catalogued as rs752018098, COSV57824879; called by muse, mutect2, varscan2
- PGLYRP4 | c.987G>A p.L329= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as COSV100668509; called by muse, mutect2, varscan2
- PHKA1 | c.3609C>T p.L1203= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as rs1556200655, COSV100262448, COSV100263836; called by muse, mutect2, varscan2
- PHLDB1 | c.954C>A p.G318= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs373984665; called by muse, mutect2, varscan2
- PIWIL4 | c.630C>T p.F210= | Silent (SNP) | VAF 70/190 reads (37%) | catalogued as rs1182818288, COSV100133396; called by muse, mutect2, varscan2
- PLCB2 | c.2565C>T p.V855= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs769618479, COSV99542546; called by muse, mutect2, varscan2
- PODXL2 | c.663G>A p.R221= | Silent (SNP) | VAF 42/66 reads (64%) | catalogued as COSV100686569; called by muse, mutect2, varscan2
- PPIAL4A | c.264C>T p.L88= | Silent (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- PRAMEF20 | c.57G>A p.R19= | Silent (SNP) | VAF 127/249 reads (51%) | called by muse, mutect2, varscan2
- PRDM1 | c.2124G>A p.G708= | Silent (SNP) | VAF 136/332 reads (41%) | catalogued as COSV100958975; called by muse, mutect2, varscan2
- PRRC2C | c.7911T>A p.P2637= (on ENST00000367742; = p.P2635= on NM_015172.4) | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1250422800, COSV100145925; called by muse, mutect2, varscan2
- PRSS22 | c.621C>T p.V207= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99361976; called by muse, mutect2, varscan2
- PSD4 | c.429C>T p.S143= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV99831425; called by muse, mutect2, varscan2
- PSG4 | c.144G>A p.G48= | Silent (SNP) | VAF 105/319 reads (33%) | catalogued as COSV99737742; called by muse, mutect2, varscan2
- PTDSS1 | c.336C>T p.F112= | Silent (SNP) | VAF 60/247 reads (24%) | catalogued as rs754925679, COSV61265951; called by muse, mutect2, varscan2
- PYGM | c.507G>A p.Q169= | Silent (SNP) | VAF 68/198 reads (34%) | catalogued as COSV99377548; called by muse, mutect2, varscan2
- RBMXL2 | c.276C>T p.S92= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1409356424, COSV100182511; called by muse, mutect2, varscan2
- RFTN1 | c.507G>A p.V169= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100489823; called by muse, mutect2, varscan2
- RP1 | c.1380G>A p.K460= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as CM1312868, COSV55125083; called by muse, mutect2, varscan2
- RP1 | c.3162G>A p.Q1054= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as COSV99608629; called by muse, mutect2, varscan2
- RP1 | c.5982C>T p.F1994= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV55118322; called by muse, mutect2, varscan2
- SCN11A | c.2274C>T p.F758= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs1559515654, COSV100182344, COSV99043403; called by muse, mutect2, varscan2
- SEC16B | c.1296C>T p.P432= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs1164924664, COSV100381886; called by muse, mutect2, varscan2
- SEMA3E | c.1920C>T p.L640= | Silent (SNP) | VAF 50/115 reads (43%) | catalogued as COSV100319473, COSV57089533; called by muse, mutect2, varscan2
- SEMA4A | c.1188C>T p.F396= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as COSV61772139; called by muse, mutect2, varscan2
- SEPTIN14 | c.492C>T p.F164= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV66431500; called by muse, mutect2
- SERPINA6 | c.9C>T p.L3= | Silent (SNP) | VAF 37/63 reads (59%) | catalogued as rs1448412973, COSV58587778; called by muse, mutect2, varscan2
- SERPINB12 | c.822G>A p.R274= | Silent (SNP) | VAF 71/174 reads (41%) | catalogued as rs1291387846, COSV54034910; called by muse, mutect2, varscan2
- SEZ6L | c.2223G>A p.R741= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV99962807; called by muse, mutect2, varscan2
- SH2D1B | c.165C>T p.I55= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV63391970; called by muse, mutect2, varscan2
- SIGLEC11 | c.2040G>A p.R680= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1394030661, COSV101357095; called by muse, mutect2
- SLA2 | c.606G>A p.K202= | Silent (SNP) | VAF 62/194 reads (32%) | catalogued as COSV53412794; called by muse, mutect2, varscan2
- SLC10A5 | c.945C>T p.F315= | Silent (SNP) | VAF 41/78 reads (53%) | catalogued as rs769155292, COSV72828589; called by muse, mutect2, varscan2
- SLC14A2 | c.774C>T p.F258= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV54906183; called by muse, mutect2, varscan2
- SLC1A5 | c.1536C>T p.V512= | Silent (SNP) | VAF 111/308 reads (36%) | catalogued as COSV101314817; called by muse, mutect2, varscan2
- SLC22A25 | c.891G>A p.K297= | Silent (SNP) | VAF 52/167 reads (31%) | catalogued as rs772527521, COSV100123912; called by muse, varscan2
- SLC29A4 | c.1065C>T p.A355= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as rs745680677, COSV99786918; called by muse, mutect2, varscan2
- SLC2A7 | c.651C>T p.P217= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1258886890, COSV101280829; called by muse, mutect2
- SLC44A5 | c.2142C>T p.P714= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV100902518; called by muse, mutect2, varscan2
- SLC4A3 | c.1137C>T p.A379= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1213134365, COSV99813148; called by muse, mutect2, varscan2
- SLC9A2 | c.504G>A p.T168= | Silent (SNP) | VAF 121/313 reads (39%) | catalogued as rs267598814, COSV52128348, COSV52134766; called by muse, mutect2, varscan2
- SOX11 | c.1020C>T p.S340= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100431368; called by muse, mutect2
- SPATA31A1 | c.3681C>T p.R1227= | Silent (SNP) | VAF 89/245 reads (36%) | called by muse, mutect2, varscan2
- SPEF2 | c.3201C>T p.F1067= | Silent (SNP) | VAF 42/76 reads (55%) | catalogued as COSV100607701; called by muse, mutect2, varscan2
- SUZ12 | c.1698C>T p.F566= | Silent (SNP) | VAF 26/38 reads (68%) | catalogued as rs11551268, COSV100496788; called by muse, mutect2, varscan2
- SYTL3 | c.1017G>A p.K339= (on ENST00000611299 / NM_001242394.1; = p.K271= on NM_001009991.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs1470289325, COSV51913449, COSV99792510; called by muse, mutect2, varscan2
- TAOK2 | c.3582C>T p.I1194= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV54230624; called by muse, mutect2, varscan2
- TBC1D21 | c.144C>T p.F48= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV100311519; called by muse, mutect2, varscan2
- TBC1D9B | c.3597C>T p.S1199= (on ENST00000356834 / NM_198868.3; = p.S1182= on NM_015043.4) | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV99481740; called by muse, mutect2, varscan2
- TDRD5 | c.1815G>A p.S605= | Silent (SNP) | VAF 61/140 reads (44%) | catalogued as rs150044249; called by muse, mutect2, varscan2
- TEAD3 | c.474C>T p.S158= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100132612; called by muse, mutect2, varscan2
- TICAM1 | c.1521C>G p.L507= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV99941259; called by muse, mutect2, varscan2
- TMEM200A | c.1041G>A p.R347= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs267600808, COSV51651813; called by muse, mutect2, varscan2
- TMPRSS4 | c.417C>T p.A139= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV101449423; called by muse, mutect2, varscan2
- TNFRSF1B | c.729C>T p.L243= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100884198; called by muse, mutect2, varscan2
- TNFSF15 | c.582C>T p.L194= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV100928338; called by muse, mutect2, varscan2
- TPO | c.1368G>A p.R456= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100221914; called by muse, mutect2, varscan2
- TRANK1 | c.7782G>A p.R2594= | Silent (SNP) | VAF 23/34 reads (68%) | catalogued as rs1182734989, COSV57143669; called by muse, mutect2, varscan2
- TRIM33 | c.2130C>T p.P710= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs752816848, COSV100635705; called by muse, mutect2, varscan2
- TRIM58 | c.1005C>T p.I335= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100825265; called by muse, mutect2, varscan2
- TRIML2 | c.291G>A p.E97= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV58716334; called by muse, mutect2
- TRIO | c.7485C>T p.S2495= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs557145602, COSV100702707; called by muse, varscan2
- TRPC4 | c.2142G>A p.V714= (on ENST00000379705 / NM_016179.4; = p.V719= on NM_003306.3) | Silent (SNP) | VAF 98/222 reads (44%) | catalogued as rs962139629, COSV100157633, COSV100157756; called by muse, mutect2, varscan2
- TRPM6 | c.5403C>T p.F1801= | Silent (SNP) | VAF 50/91 reads (55%) | catalogued as rs749496387, COSV62513125; called by muse, mutect2, varscan2
- TRPS1 | c.2607G>A p.Q869= (on ENST00000220888 / NM_001330599.2; = p.Q882= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as COSV99633903; called by muse, mutect2, varscan2
- TRPV5 | c.1533T>A p.I511= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as COSV99520963; called by muse, mutect2, varscan2
- TSPAN33 | c.339C>T p.I113= | Silent (SNP) | VAF 72/233 reads (31%) | catalogued as COSV56825915, COSV99179797; called by muse, varscan2
- TSR3 | c.474G>A p.R158= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV50103481, COSV99136361; called by muse, mutect2, varscan2
- TTC22 | c.99C>T p.F33= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100827727, COSV64023881; called by muse, mutect2, varscan2
- UBE3D | c.996A>G p.K332= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV99388956; called by muse, mutect2, varscan2
- UBQLNL | c.492G>A p.L164= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as COSV100975438; called by muse, mutect2
- UBR4 | c.10695C>T p.L3565= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV100921671; called by muse, mutect2, varscan2
- UQCRFS1 | c.408C>T p.F136= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs764576836, COSV59184881; called by muse, mutect2, varscan2
- USH2A | c.14511C>T p.I4837= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs139847770; ClinVar: likely benign; called by muse, mutect2, varscan2
- VARS1 | c.1503C>T p.L501= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as rs767371765, COSV100989960; called by muse, mutect2, varscan2
- WIPF3 | c.195C>T p.I65= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99635139; called by muse, mutect2, varscan2
- ZMYND8 | c.1530C>T p.S510= (on ENST00000311275 / NM_001363741.2; = p.S530= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/142 reads (44%) | catalogued as COSV99521189; called by muse, mutect2, varscan2
- ZNF280A | c.237C>T p.F79= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as rs375668247; called by muse, mutect2, varscan2
- ZNF334 | c.1818G>A p.G606= | Silent (SNP) | VAF 63/149 reads (42%) | catalogued as COSV61618124; called by muse, mutect2, varscan2
- ZNF391 | c.858C>T p.F286= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99772794; called by muse, mutect2, varscan2
- ZNF496 | c.1164C>T p.S388= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV54175855; called by muse, mutect2, varscan2
- ZNF564 | c.351C>T p.S117= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV59434724; called by muse, mutect2, varscan2
- ZNF669 | c.693C>T p.F231= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as rs369097150; called by muse, mutect2, varscan2
- ZNF831 | c.3378C>T p.S1126= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV100926222; called by muse, mutect2, varscan2
- AL136982.4 | n.813C>T | RNA (SNP) | VAF 38/64 reads (59%) | catalogued as rs200535133; called by muse, mutect2, varscan2
- C12orf77 | n.214G>A | RNA (SNP) | VAF 22/62 reads (35%) | catalogued as rs748065726; called by muse, mutect2, varscan2
- CR1 | c.487+11992G>A | Intron (SNP) | VAF 32/79 reads (41%) | catalogued as COSV100888000; called by muse, mutect2, varscan2
- MIR184 | n.59G>A | RNA (SNP) | VAF 60/131 reads (46%) | called by muse, mutect2, varscan2
- NXF5 | n.978G>A | RNA (SNP) | VAF 21/38 reads (55%) | catalogued as COSV99534617; called by muse, mutect2, varscan2
- RAVER1 | c.1432-40C>T | Intron (SNP) | VAF 10/27 reads (37%) | catalogued as rs1390527715, COSV53347258, COSV99533111; called by muse, mutect2, varscan2
- SLC39A14 | c.457+1613C>T | Intron (SNP) | VAF 44/131 reads (34%) | catalogued as rs148403209; called by muse, mutect2, varscan2
- SNORD116-22 | n.30C>T | RNA (SNP) | VAF 161/473 reads (34%) | catalogued as rs372106752; called by muse, mutect2, varscan2
